Gene-level copy-number profile of tumor specimen TCGA-J8-A4HW-01A from TCGA case TCGA-J8-A4HW, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 59.1 years (21,587 days).
Specimen TCGA-J8-A4HW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-THCA.1d088a8e-c593-4ed7-a391-2adf2ddb67df.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-J8-A4HW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 348 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fdc82acd-74fd-4b80-8687-4e426091c7c2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 521; copy number 1: 750; copy number 2: 58,982; copy number 3: 12; copy number 5: 7; copy number 6: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-J8-A4HW-01A-11D-A256-01): tumor purity 0.67, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:115,299,588–115,332,566, 3 genes, copy number 6 (within-gene range 2–6): AC078880.3, AC078880.4, AC078880.5.
- chr15:31,765,743–32,186,475, 6 genes, copy number 5: DEPDC1P1, AC026951.1, CHRNA7, AC079969.1, Y_RNA, AC068448.1.
- chr21:45,914,296–45,919,483, 1 gene, copy number 5: AJ239328.1.

Autosomal genes at a single copy (total copy number 1): 750. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
